Somatic mutation profile of tumor specimen ALCH-AENW-TTP1-A (aliquot ALCH-AENW-TTP1-A-2-0-D-A673-36) from ALCHEMIST case ALCH-AENW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.6 years (23,600 days).
Specimen ALCH-AENW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05aeb666-f771-4bc1-9636-3ffe06c305e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENW-NB1-A (Blood Derived Normal), aliquot ALCH-AENW-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09165596-4fe1-495e-8970-c8dbf5121977

The open-access MAF lists 392 somatic variants for this specimen: 272 protein-altering or splice-affecting, 82 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 82, Intron 19, Frame Shift Del 15, Nonsense Mutation 14, Splice Site 10, RNA 9, 3'UTR 8, Splice Region 3, Frame Shift Ins 2, Nonstop Mutation 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 86/401 reads (21%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ACVR1B | c.461G>C p.R154P | Missense Mutation (SNP) | VAF 159/648 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV57777057; called by muse, mutect2, varscan2
- ADAMTS16 | c.1118T>C p.M373T | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV99942876; called by muse, mutect2, varscan2
- ANKRD30B | c.2068G>T p.G690* | Nonsense Mutation (SNP) | VAF 57/276 reads (21%) | catalogued as COSV62814368; called by muse, mutect2, varscan2
- CACTIN | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.454); catalogued as COSV50271305; called by muse, mutect2
- CAPN10 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs759635598; called by muse, mutect2, varscan2
- CARMIL2 | c.2857G>C p.G953R | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as rs772703231; called by muse, mutect2, varscan2
- CCDC171 | c.2605A>G p.S869G | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1371513176; called by muse, mutect2, varscan2
- CCDC83 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 84/529 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as COSV99721448; called by muse, mutect2, varscan2
- CDH12 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 48/1138 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV66423265; called by muse, mutect2
- CDH23 | c.865A>G p.I289V | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.486); catalogued as rs765965046; called by muse, mutect2
- CDH9 | c.2149C>G p.H717D | Missense Mutation (SNP) | VAF 96/506 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.102); catalogued as COSV50276366; called by muse, mutect2, varscan2
- CENPI | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV54504121; called by muse, mutect2, varscan2
- CHST4 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58298018; called by muse, mutect2, varscan2
- CNTN1 | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 74/624 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs267603461; called by muse, mutect2, varscan2
- COL5A3 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53410872; called by muse, mutect2, varscan2
- CSMD2 | c.9178G>A p.G3060R | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160716390; called by muse, mutect2, varscan2
- DNAH9 | c.7306G>A p.V2436I | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs772781273; called by muse, mutect2, varscan2
- DNAJC6 | c.2702G>T p.W901L | Missense Mutation (SNP) | VAF 113/493 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380186979; called by muse, mutect2, varscan2
- ELOVL4 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 81/510 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs753592451; called by muse, mutect2, varscan2
- ERBB3 | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 84/474 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.299); catalogued as COSV57247809; called by muse, mutect2, varscan2
- ERCC4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 67/312 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV61314511; called by muse, mutect2, varscan2
- EXT1 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 129/376 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as CD000603; called by muse, mutect2, varscan2
- FAM180A | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs770463007; called by muse, mutect2, varscan2
- FHIT | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 126/449 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100535039; called by muse, mutect2, varscan2
- FIZ1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1327204837; called by muse, mutect2
- GATA3 | c.921+1G>C p.X307_splice | Splice Site (SNP) | VAF 118/451 reads (26%) | catalogued as rs111283999; called by muse, mutect2, varscan2
- GBA3 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 107/684 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs367674331; called by muse, mutect2, varscan2
- GRHL3 | c.1288G>A p.V430I (on ENST00000350501 / NM_198174.3; = p.V435I on NM_021180.3) | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs199801227, COSV52565046; called by muse, mutect2, varscan2
- GRIN2A | c.1213C>A p.H405N | Missense Mutation (SNP) | VAF 124/625 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58046468; called by muse, mutect2, varscan2
- H2BC1 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV51236761; called by muse, mutect2, varscan2
- HAPLN4 | c.817G>T p.G273W | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99363867; called by muse, mutect2, varscan2
- HOXA11 | c.273A>T p.R91S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770144872; called by muse, mutect2, varscan2
- HPX | c.841C>A p.H281N | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV56418473; called by muse, mutect2, varscan2
- KCNB2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049880; called by muse, mutect2, varscan2
- KCNJ3 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 37/380 reads (10%) | catalogued as rs951927978, COSV99715026; called by muse, mutect2
- KRT83 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs766185773; called by muse, mutect2, varscan2
- LRP1B | c.8314C>T p.R2772C | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as rs1247290776; called by muse, mutect2, varscan2
- MAGEB10 | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 67/176 reads (38%) | catalogued as COSV100775414; called by muse, mutect2, varscan2
- NIBAN1 | c.1990G>T p.V664L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs75030920; called by muse, mutect2, varscan2
- NUF2 | c.179G>C p.R60P | Missense Mutation (SNP) | VAF 40/639 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV99616691; called by muse, mutect2
- NUTM1 | c.3280C>A p.L1094I | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs775243567; called by muse, mutect2, varscan2
- OR2G3 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV100180749; called by muse, mutect2
- PCDH11X | c.2963C>A p.P988H | Missense Mutation (SNP) | VAF 223/502 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.534); catalogued as COSV53486874; called by muse, mutect2, varscan2
- PCDH8 | c.2996G>C p.R999P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV58810925; called by muse, mutect2, varscan2
- PCSK9 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1182044412; called by muse, mutect2, varscan2
- PGBD1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 188/587 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV99460663; called by muse, mutect2, varscan2
- PHACTR3 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100732133; called by muse, mutect2, varscan2
- POLE | c.5889G>T p.E1963D | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV57683805; called by muse, mutect2, varscan2
- POP1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 252/765 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs150132872; called by muse, mutect2, varscan2
- PPP1R3A | c.2323C>G p.P775A | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs760472013; called by muse, mutect2, varscan2
- PRAMEF15 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 106/602 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.942); catalogued as rs1485250520; called by muse, mutect2, varscan2
- RIMS1 | c.3916A>G p.T1306A | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1327252678; called by muse, mutect2, varscan2
- RUNX1T1 | c.1778C>A p.P593Q (on ENST00000265814 / NM_001198628.1; = p.P566Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV56143335, COSV56149645; called by muse, mutect2, varscan2
- RYR2 | c.6034G>T p.D2012Y | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV100768926; called by muse, mutect2, varscan2
- RYR2 | c.7679C>A p.S2560* | Nonsense Mutation (SNP) | VAF 120/676 reads (18%) | catalogued as COSV63702775; called by muse, mutect2, varscan2
- SAP130 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs377240674; called by muse, varscan2
- SCN10A | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 97/405 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV71861762; called by muse, mutect2, varscan2
- SH2B1 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs547678855; called by mutect2, varscan2
- SORBS3 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs144354172; called by muse, mutect2, varscan2
- SPDYE4 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.152); catalogued as rs925123396, COSV60905726; called by muse, mutect2, varscan2
- SPTA1 | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 82/807 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63752353; called by muse, mutect2, varscan2
- SYT11 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs749783469, COSV64175798; called by muse, mutect2
- TF | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53917690; called by muse, mutect2
- TFPI2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.726); catalogued as COSV55991360; called by muse, mutect2, varscan2
- TNN | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53428493; called by muse, mutect2, varscan2
- TNR | c.4037G>A p.R1346H | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs200613814; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 32/155 reads (21%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TP63 | c.414C>A p.H138Q | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53197864; called by muse, mutect2, varscan2
- TROAP | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57743993; called by muse, mutect2, varscan2
- TSPY3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 140/365 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs771675793; called by muse, mutect2, varscan2
- UGT2B10 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 22/621 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as rs1374046959; called by muse, mutect2
- UNC80 | c.3700C>G p.R1234G | Missense Mutation (SNP) | VAF 47/486 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104380979; called by muse, mutect2, varscan2
- VNN1 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61729579, COSV63389534, COSV63391843; called by muse, mutect2, varscan2
- VPS13B | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 34/469 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376296532; called by muse, mutect2
- VPS13D | c.2650A>G p.I884V | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.219); catalogued as COSV99169450; called by muse, mutect2, varscan2
- ZFHX4 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as rs1050373982, COSV51473220; called by muse, mutect2, varscan2
- ZNF257 | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs766105689, COSV71309806; called by muse, mutect2, varscan2
- ZNF556 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1211251995, COSV56914240; called by muse, mutect2, varscan2
- ABCA12 | c.7549C>G p.H2517D (on ENST00000272895 / NM_173076.3; = p.H2199D on NM_015657.3) | Missense Mutation (SNP) | VAF 83/643 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ABCA9 | c.86A>C p.Q29P | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2
- ABRA | c.444_447del p.D148Efs*22 | Frame Shift Del (DEL) | VAF 63/372 reads (17%) | called by mutect2, pindel, varscan2
- ACOT12 | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE3 | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ADGRF2 | c.2029G>T p.A677S (on ENST00000296862 / NM_001368115.2; = p.A609S on NM_153839.7) | Missense Mutation (SNP) | VAF 157/389 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ADGRG7 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- ADRA1D | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGR2 | c.330+1del p.X110_splice | Splice Site (DEL) | VAF 74/300 reads (25%) | called by mutect2, pindel, varscan2
- AGXT | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AK9 | c.5688G>T p.K1896N | Missense Mutation (SNP) | VAF 82/541 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AKAP9 | c.11767A>G p.T3923A (on ENST00000359028; = p.T3899A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/594 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- ALG10 | c.1331A>T p.Y444F | Missense Mutation (SNP) | VAF 117/478 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by mutect2, varscan2
- ANKRD12 | c.925del p.D309Mfs*14 | Frame Shift Del (DEL) | VAF 50/306 reads (16%) | called by mutect2, pindel, varscan2
- AP3B2 | c.1157A>C p.D386A | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARFGEF1 | c.1264del p.D422Mfs*4 | Frame Shift Del (DEL) | VAF 110/697 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP18 | c.1232C>G p.P411R | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP27 | c.1885G>T p.D629Y (on ENST00000428638 / NM_001282290.1; = p.D288Y on NM_199282.3) | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ARSK | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ASCC2 | c.1997A>G p.D666G | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASZ1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP11B | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 17/393 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ATP6V0D2 | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 107/621 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B4GALNT2 | c.641-1G>T p.X214_splice | Splice Site (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- BLZF1 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 182/1006 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- C1QL3 | c.709C>A p.H237N | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- CACNA1C | c.2923C>A p.L975M | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, varscan2
- CADM3 | c.302C>G p.A101G (on ENST00000368125 / NM_001127173.3; = p.A135G on NM_021189.5) | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CAND2 | c.1985G>T p.R662L (on ENST00000456430 / NM_001162499.2; = p.R569L on NM_012298.3) | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC168 | c.7296del p.W2432Cfs*33 | Frame Shift Del (DEL) | VAF 62/338 reads (18%) | called by mutect2, pindel, varscan2
- CCNB3 | c.3064G>T p.G1022W | Missense Mutation (SNP) | VAF 144/357 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CDH9 | c.126del p.D43Mfs*32 | Frame Shift Del (DEL) | VAF 162/1189 reads (14%) | called by mutect2, pindel, varscan2
- CEP164 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); called by muse, mutect2
- CHRNA3 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CLC | c.122A>T p.H41L | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CNTN4 | c.2812G>A p.V938I | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CROCC2 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.035); called by muse, varscan2
- CTNND2 | c.1593G>T p.R531S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CYFIP1 | c.1180del p.A394Rfs*15 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- DDR2 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 67/382 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH1 | c.7155G>T p.W2385C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DPY19L4 | c.1005G>T p.L335= | Splice Region (SNP) | VAF 69/407 reads (17%) | called by muse, mutect2, varscan2
- DST | c.13445C>G p.S4482C (on ENST00000361203 / NM_001374722.1; = p.S2070C on NM_015548.5) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- DST | c.7791T>G p.D2597E | Missense Mutation (SNP) | VAF 14/417 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.173); called by muse, mutect2
- DUSP22 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2
- EPHA6 | c.3391T>G p.*1131Gext*14 | Nonstop Mutation (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- ERP44 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EVX1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- F12 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 103/355 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FAM114A1 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
- FAM240A | c.34G>T p.G12W (on ENST00000444264; = p.G6W on NM_001195442.2) | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FAM47A | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FAT3 | c.12595G>C p.A4199P | Missense Mutation (SNP) | VAF 95/340 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBXL5 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- FBXO47 | c.1010T>A p.F337Y | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GABRG2 | c.910G>T p.V304F (on ENST00000361925 / NM_001375343.1; = p.V264F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 210/688 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GALNT3 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 79/639 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR162 | c.1675C>A p.R559S (on ENST00000311268 / NM_019858.2; = p.R275S on NM_014449.2) | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GRAMD1A | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GRIK2 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- GRIN2A | c.1212C>A p.N404K | Missense Mutation (SNP) | VAF 122/619 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- GUCY1A2 | c.1810C>A p.L604M | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.402); called by muse, mutect2
- HJURP | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- HOXA9 | c.7A>C p.T3P | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- HOXB9 | c.573del p.Y192Tfs*9 | Frame Shift Del (DEL) | VAF 27/227 reads (12%) | called by mutect2, pindel, varscan2
- HSP90B1 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HSPBAP1 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- HTR1B | c.344G>C p.W115S | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYDIN | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.2334G>C p.L778F | Missense Mutation (SNP) | VAF 30/756 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2
- ICE1 | c.4073G>T p.G1358V | Missense Mutation (SNP) | VAF 104/690 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHA1 | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL31RA | c.255C>A p.Y85* | Nonsense Mutation (SNP) | VAF 64/622 reads (10%) | called by muse, mutect2, varscan2
- ITGA1 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA10 | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ITGAX | c.38-1G>T p.X13_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- JCHAIN | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 183/582 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- KCND2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNK2 | c.412C>T p.Q138* (on ENST00000444842 / NM_001017425.3; = p.Q123* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 60/769 reads (8%) | called by muse, mutect2
- KCTD3 | c.441T>A p.D147E | Missense Mutation (SNP) | VAF 13/387 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- KIAA0586 | c.3948C>T p.D1316= (on ENST00000619416 / NM_001244190.2; = p.D1255= on NM_014749.5) | Splice Region (SNP) | VAF 18/106 reads (17%) | called by muse, varscan2
- KIF5C | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2
- KLF12 | c.518T>A p.M173K | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KRT77 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP27-1 | c.82A>T p.I28L | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- KRTAP5-1 | c.527del p.G176Afs*? | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | called by mutect2, varscan2
- L3MBTL4 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LAMA1 | c.1790T>A p.V597E | Missense Mutation (SNP) | VAF 136/632 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LAMA2 | c.3509G>A p.G1170D | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- LAMC1 | c.4123A>T p.R1375W | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2
- LILRA5 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LLCFC1 | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRFN5 | c.754A>T p.R252W | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LZTFL1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- MAGEB10 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by mutect2, varscan2
- MAGIX | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP7 | c.1493A>T p.E498V | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCO | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MEPCE | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MGA | c.2384G>T p.W795L | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MMP2 | c.1161G>T p.W387C | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MNDA | c.167T>A p.F56Y | Missense Mutation (SNP) | VAF 42/579 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.416); called by muse, mutect2
- MSC | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MSC | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MUC17 | c.7753C>A p.P2585T | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MYL9 | c.120G>C p.M40I | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.523); called by muse, mutect2
- MYO5C | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 53/485 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NACAD | c.2750C>A p.P917H | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, varscan2
- NAV3 | c.3538G>T p.E1180* | Nonsense Mutation (SNP) | VAF 111/478 reads (23%) | called by muse, mutect2, varscan2
- NOVA1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 206/585 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR10T2 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 87/468 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR5L1 | c.648del p.S217Pfs*4 | Frame Shift Del (DEL) | VAF 82/596 reads (14%) | called by mutect2, varscan2
- OR8D1 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 92/410 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OSBPL6 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 54/624 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- OTOF | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OXR1 | c.1352A>T p.D451V (on ENST00000442977 / NM_001198532.1; = p.D450V on NM_018002.3) | Missense Mutation (SNP) | VAF 252/655 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- PBX4 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PCDH8 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCSK7 | c.639C>G p.D213E | Missense Mutation (SNP) | VAF 167/523 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDGFC | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PITPNM2 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIWIL1 | c.2460C>A p.Y820* | Nonsense Mutation (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2
- PLCXD3 | c.437A>T p.H146L | Missense Mutation (SNP) | VAF 94/730 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PLEKHA7 | c.2904G>T p.E968D | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PLXNB2 | c.4917C>G p.F1639L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PREX1 | c.2867C>A p.P956H | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PRKAG2 | c.1125C>A p.Y375* | Nonsense Mutation (SNP) | VAF 80/835 reads (10%) | called by muse, mutect2, varscan2
- PRRC2B | c.2966A>G p.E989G | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PRUNE2 | c.2512A>G p.K838E | Missense Mutation (SNP) | VAF 91/465 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PSG3 | c.1157C>A p.T386K | Missense Mutation (SNP) | VAF 52/580 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.142); called by muse, mutect2
- PTPRB | c.5292+1G>T p.X1764_splice | Splice Site (SNP) | VAF 20/182 reads (11%) | called by muse, mutect2, varscan2
- RBM10 | c.2446del p.D816Tfs*31 | Frame Shift Del (DEL) | VAF 95/285 reads (33%) | called by mutect2, pindel, varscan2
- RBM33 | c.3512G>C p.*1171Sext*40 | Nonstop Mutation (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- RHBDF1 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- RPTN | c.2259C>A p.S753R | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RUNX1T1 | c.1400C>A p.A467D (on ENST00000265814 / NM_001198628.1; = p.A440D on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SBNO2 | c.1739C>A p.A580E | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SCN2B | c.385A>T p.I129F | Missense Mutation (SNP) | VAF 151/849 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SERPINB9 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 238/659 reads (36%) | called by muse, mutect2, varscan2
- SH2D4B | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 65/254 reads (26%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SH3RF3 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SHISA9 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SLC1A7 | c.698-1G>T p.X233_splice | Splice Site (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- SLC22A1 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- SLC24A3 | c.423+2T>G p.X141_splice | Splice Site (SNP) | VAF 26/239 reads (11%) | called by muse, mutect2, varscan2
- SLC25A17 | c.650_653dup p.V219Hfs*19 | Frame Shift Ins (INS) | VAF 43/259 reads (17%) | called by mutect2, pindel, varscan2
- SLC27A6 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 103/378 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC32A1 | c.1092C>G p.D364E | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SLCO4A1 | c.887G>C p.R296P | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, varscan2
- SMAD2 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 87/753 reads (12%) | called by muse, mutect2, varscan2
- SMAD4 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 22/477 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STON1 | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- STXBP5 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TAF5 | c.2332A>T p.T778S | Missense Mutation (SNP) | VAF 78/349 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TDRD7 | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 110/796 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TENM2 | c.7000del p.H2334Mfs*52 (on ENST00000518659 / NM_001122679.2; = p.H2095Mfs*52 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 66/261 reads (25%) | called by mutect2, pindel, varscan2
- TEX55 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TIAM1 | c.4569C>A p.D1523E | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM128 | c.450G>T p.L150F (on ENST00000382753 / NM_001297552.2; = p.L126F on NM_032927.3) | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM132B | c.3108C>A p.D1036E | Missense Mutation (SNP) | VAF 146/585 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TMEM132C | c.840C>G p.S280R | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM260 | c.1516A>T p.N506Y | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TNFRSF10C | c.652G>C p.G218R | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); called by muse, varscan2
- TP53BP1 | c.3992G>T p.G1331V | Missense Mutation (SNP) | VAF 39/537 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2
- TP53INP1 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 40/606 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2
- TRAPPC8 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 120/759 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- TRBV29-1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 87/450 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRBV6-1 | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TRIM49B | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 54/561 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TRPV6 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRRAP | c.5357A>G p.E1786G (on ENST00000359863 / NM_001244580.1; = p.E1768G on NM_003496.3) | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TTN | c.9627G>T p.E3209D (on ENST00000591111; = p.E3163D on NM_003319.4) | Missense Mutation (SNP) | VAF 157/679 reads (23%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UNK | c.1741G>T p.V581F | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- URB2 | c.2845C>T p.L949F | Missense Mutation (SNP) | VAF 38/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- USP13 | c.2098del p.A700Lfs*4 | Frame Shift Del (DEL) | VAF 39/164 reads (24%) | called by mutect2, pindel, varscan2
- VIT | c.634A>G p.S212G | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- VWA3A | c.990+1G>T p.X330_splice | Splice Site (SNP) | VAF 42/193 reads (22%) | called by muse, mutect2, varscan2
- VWF | c.7193G>T p.C2398F | Missense Mutation (SNP) | VAF 55/513 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY4 | c.8260del p.H2754Ifs*3 | Frame Shift Del (DEL) | VAF 44/392 reads (11%) | called by mutect2, pindel, varscan2
- XIRP2 | c.3755C>A p.S1252Y (on ENST00000628543; = p.S1427Y on NM_152381.6) | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- XIRP2 | c.6864G>C p.Q2288H (on ENST00000628543; = p.Q2463H on NM_152381.6) | Missense Mutation (SNP) | VAF 70/378 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- XPC | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2
- ZBTB8B | c.868_869insA p.A290Dfs*6 | Frame Shift Ins (INS) | VAF 62/295 reads (21%) | called by mutect2, pindel, varscan2
- ZCCHC2 | c.1548G>T p.V516= | Splice Region (SNP) | VAF 59/279 reads (21%) | called by muse, mutect2, varscan2
- ZIM2 | c.1331T>A p.L444* | Nonsense Mutation (SNP) | VAF 95/410 reads (23%) | called by muse, mutect2, varscan2
- ZNF343 | c.1553A>T p.E518V | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF407 | c.5129-2A>C p.X1710_splice | Splice Site (SNP) | VAF 78/402 reads (19%) | called by muse, varscan2
- ZNF469 | c.5494G>T p.A1832S (on ENST00000437464; = p.A1860S on NM_001367624.2) | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ZNF8 | c.194-1G>T p.X65_splice | Splice Site (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- ZNF91 | c.1678A>T p.T560S | Missense Mutation (SNP) | VAF 35/365 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.015); called by muse, mutect2
- ZP2 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- ZSCAN5B | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTC1 | c.414C>T p.I138= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- ADGRL2 | c.729C>A p.A243= | Silent (SNP) | VAF 128/517 reads (25%) | called by muse, mutect2, varscan2
- AL592490.1 | c.1332G>A p.L444= | Silent (SNP) | VAF 40/217 reads (18%) | called by muse, varscan2
- APBB3 | c.1233C>T p.Y411= (on ENST00000357560 / NM_133173.2; = p.Y418= on NM_006051.3) | Silent (SNP) | VAF 76/267 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.3312G>C p.V1104= | Silent (SNP) | VAF 86/278 reads (31%) | called by muse, mutect2, varscan2
- AUTS2 | c.1569G>A p.E523= | Silent (SNP) | VAF 81/353 reads (23%) | catalogued as rs1389463896; called by muse, mutect2, varscan2
- BACE2 | c.384G>T p.T128= | Silent (SNP) | VAF 55/287 reads (19%) | called by muse, mutect2, varscan2
- BAG3 | c.783G>T p.R261= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- C1QL1 | c.516C>A p.G172= | Silent (SNP) | VAF 122/498 reads (24%) | catalogued as COSV53647340; called by muse, mutect2, varscan2
- CCDC91 | c.318G>T p.V106= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- CD207 | c.750C>A p.I250= | Silent (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- CDH9 | c.2148C>A p.I716= | Silent (SNP) | VAF 97/514 reads (19%) | called by muse, mutect2, varscan2
- CLDN14 | c.579C>A p.P193= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- CLDN14 | c.339C>A p.A113= | Silent (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1590A>G p.S530= | Silent (SNP) | VAF 83/390 reads (21%) | called by muse, mutect2, varscan2
- CR1 | c.5415C>A p.T1805= | Silent (SNP) | VAF 102/585 reads (17%) | called by muse, mutect2, varscan2
- CUX2 | c.4197G>T p.S1399= | Silent (SNP) | VAF 95/304 reads (31%) | catalogued as COSV55632055; called by muse, mutect2, varscan2
- CYP3A5 | c.12C>A p.I4= | Silent (SNP) | VAF 81/415 reads (20%) | called by muse, mutect2, varscan2
- DDX1 | c.2040A>T p.P680= | Silent (SNP) | VAF 98/584 reads (17%) | called by muse, mutect2, varscan2
- DDX47 | c.1062A>C p.T354= | Silent (SNP) | VAF 56/247 reads (23%) | called by muse, varscan2
- DISC1 | c.2241G>A p.K747= | Silent (SNP) | VAF 46/902 reads (5%) | called by muse, mutect2
- EDN3 | c.213G>T p.L71= | Silent (SNP) | VAF 66/294 reads (22%) | catalogued as rs1284939928; called by mutect2, varscan2
- EYS | c.3096T>C p.S1032= | Silent (SNP) | VAF 71/593 reads (12%) | called by muse, mutect2, varscan2
- FBLN2 | c.2073G>A p.Q691= | Silent (SNP) | VAF 87/306 reads (28%) | catalogued as COSV55482031; called by muse, mutect2, varscan2
- FLG2 | c.3405A>T p.T1135= | Silent (SNP) | VAF 29/276 reads (11%) | catalogued as COSV66168259; called by muse, mutect2, varscan2
- FMN2 | c.270C>A p.A90= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV60417658; called by muse, mutect2, varscan2
- GIN1 | c.1125A>G p.K375= | Silent (SNP) | VAF 61/475 reads (13%) | catalogued as rs782096229; called by muse, mutect2, varscan2
- GML | c.438G>T p.L146= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as COSV55277971; called by muse, mutect2
- GPR158 | c.1212T>C p.D404= | Silent (SNP) | VAF 118/532 reads (22%) | called by muse, mutect2, varscan2
- GRIK4 | c.570C>A p.S190= | Silent (SNP) | VAF 47/232 reads (20%) | called by muse, mutect2, varscan2
- HEATR3 | c.243G>T p.V81= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- HTR7 | c.1167G>A p.R389= | Silent (SNP) | VAF 22/322 reads (7%) | called by muse, mutect2
- IL16 | c.723C>T p.P241= | Silent (SNP) | VAF 16/264 reads (6%) | catalogued as rs1385083675; called by muse, mutect2
- IL16 | c.1642C>T p.L548= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs1176369623; called by muse, mutect2
- IL17F | c.69C>T p.A23= | Silent (SNP) | VAF 69/673 reads (10%) | catalogued as COSV60235031; called by muse, mutect2
- IREB2 | c.402C>T p.F134= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- ITGA11 | c.2709G>A p.K903= | Silent (SNP) | VAF 27/249 reads (11%) | called by muse, mutect2, varscan2
- ITIH5 | c.591C>T p.I197= | Silent (SNP) | VAF 20/205 reads (10%) | catalogued as rs369114884, COSV56904119, COSV56912641; called by muse, mutect2, varscan2
- JPH2 | c.708C>A p.R236= | Silent (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- KIR3DL1 | c.207C>A p.P69= | Silent (SNP) | VAF 54/440 reads (12%) | catalogued as COSV58492319; called by muse, varscan2
- KMT2C | c.7800G>T p.P2600= | Silent (SNP) | VAF 49/252 reads (19%) | catalogued as rs1191258031, COSV51433617; called by muse, mutect2, varscan2
- KRTAP6-3 | c.240T>C p.Y80= | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as rs1568893343; called by muse, mutect2, varscan2
- MCC | c.573C>T p.H191= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs1164226757; called by muse, mutect2, varscan2
- OCSTAMP | c.1410C>A p.P470= | Silent (SNP) | VAF 42/289 reads (15%) | called by muse, mutect2, varscan2
- ONECUT2 | c.54C>T p.C18= | Silent (SNP) | VAF 49/180 reads (27%) | called by muse, mutect2, varscan2
- OR5W2 | c.582C>A p.V194= | Silent (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- OSBPL3 | c.1425C>T p.V475= | Silent (SNP) | VAF 34/259 reads (13%) | catalogued as COSV57662294; called by muse, mutect2, varscan2
- OVCH1 | c.537C>A p.G179= | Silent (SNP) | VAF 62/333 reads (19%) | called by muse, varscan2
- PCDH15 | c.3627C>A p.L1209= | Silent (SNP) | VAF 140/944 reads (15%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.834A>G p.T278= | Silent (SNP) | VAF 58/203 reads (29%) | catalogued as rs770047743; called by muse, mutect2, varscan2
- PLCB4 | c.702T>A p.T234= | Silent (SNP) | VAF 73/304 reads (24%) | called by muse, mutect2, varscan2
- PLCL1 | c.2415G>T p.G805= | Silent (SNP) | VAF 65/564 reads (12%) | called by muse, mutect2, varscan2
- PLG | c.1077G>A p.T359= | Silent (SNP) | VAF 24/272 reads (9%) | catalogued as rs1478937955, COSV51984374, COSV99805209; called by muse, mutect2
- PNPLA5 | c.72C>T p.H24= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs748898005, COSV99336465; called by muse, mutect2, varscan2
- POLA1 | c.4104G>T p.G1368= | Silent (SNP) | VAF 98/262 reads (37%) | called by muse, mutect2, varscan2
- PPP1R12A | c.2343C>T p.S781= | Silent (SNP) | VAF 99/347 reads (29%) | catalogued as rs778997256; called by muse, mutect2, varscan2
- PPP1R26 | c.1746C>G p.L582= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs1472246139; called by muse, mutect2, varscan2
- PRKCA | c.480G>C p.G160= | Silent (SNP) | VAF 50/315 reads (16%) | catalogued as COSV52594196; called by muse, mutect2, varscan2
- PRLR | c.1731A>G p.K577= | Silent (SNP) | VAF 111/777 reads (14%) | called by muse, mutect2, varscan2
- PRUNE2 | c.2175G>T p.L725= | Silent (SNP) | VAF 41/248 reads (17%) | catalogued as COSV100944769; called by muse, mutect2, varscan2
- PTPRC | c.1176A>T p.P392= | Silent (SNP) | VAF 95/769 reads (12%) | called by muse, mutect2, varscan2
- PTPRT | c.534C>T p.A178= | Silent (SNP) | VAF 46/351 reads (13%) | catalogued as rs760289161, COSV100631765, COSV62011805; called by muse, mutect2, varscan2
- RABL2A | c.501G>A p.V167= | Silent (SNP) | VAF 24/233 reads (10%) | catalogued as rs1410832350; called by muse, mutect2, varscan2
- RGL3 | c.534G>C p.A178= | Silent (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- RGS9 | c.1167C>T p.D389= | Silent (SNP) | VAF 93/546 reads (17%) | catalogued as rs539179005, COSV52224261; called by muse, mutect2, varscan2
- ROR2 | c.1017G>A p.P339= | Silent (SNP) | VAF 32/347 reads (9%) | catalogued as rs1337548059, COSV65219868; ClinVar: likely benign; called by muse, mutect2
- SAFB | c.1836G>A p.R612= | Silent (SNP) | VAF 21/276 reads (8%) | catalogued as COSV52650160; called by muse, mutect2
- SFXN2 | c.879A>T p.P293= | Silent (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- SLC12A7 | c.744G>T p.L248= | Silent (SNP) | VAF 62/279 reads (22%) | called by muse, mutect2, varscan2
- SLC25A11 | c.852G>A p.P284= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs566786695, COSV99337251; called by muse, mutect2, varscan2
- SPATA31D1 | c.3237C>A p.V1079= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as rs374124047; called by muse, mutect2, varscan2
- SPOCD1 | c.2649C>T p.A883= | Silent (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- SPTBN4 | c.6262C>A p.R2088= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100150688; called by muse, mutect2, varscan2
- SYNE3 | c.2706G>T p.G902= | Silent (SNP) | VAF 44/336 reads (13%) | catalogued as COSV100516443; called by muse, mutect2, varscan2
- TGIF2LX | c.396C>A p.A132= | Silent (SNP) | VAF 106/284 reads (37%) | catalogued as COSV52214464, COSV99383513; called by muse, mutect2, varscan2
- THSD1 | c.1581G>C p.L527= | Silent (SNP) | VAF 66/256 reads (26%) | catalogued as COSV51628100; called by muse, mutect2, varscan2
- TMC7 | c.519G>C p.L173= | Silent (SNP) | VAF 42/492 reads (9%) | catalogued as COSV58587784; called by muse, mutect2
- TNFRSF11B | c.180C>A p.T60= | Silent (SNP) | VAF 132/660 reads (20%) | catalogued as COSV52069734; called by muse, varscan2
- TNN | c.333G>T p.R111= | Silent (SNP) | VAF 71/218 reads (33%) | called by muse, mutect2, varscan2
- TRAV10 | c.261G>T p.L87= | Silent (SNP) | VAF 64/292 reads (22%) | called by mutect2, varscan2
- TRIM55 | c.588C>T p.T196= | Silent (SNP) | VAF 42/322 reads (13%) | called by muse, mutect2, varscan2
- USH2A | c.11427C>A p.V3809= | Silent (SNP) | VAF 114/722 reads (16%) | catalogued as COSV56353260; called by muse, varscan2
- AC009533.1 | n.419G>C | RNA (SNP) | VAF 18/82 reads (22%) | called by mutect2, varscan2
- AC023469.1 | n.290C>A | RNA (SNP) | VAF 50/400 reads (13%) | called by muse, mutect2, varscan2
- AC084879.1 | n.1193C>T | RNA (SNP) | VAF 43/389 reads (11%) | catalogued as rs543216081; called by muse, mutect2, varscan2
- ALG9 | c.1712+4351T>C | Intron (SNP) | VAF 24/646 reads (4%) | called by muse, mutect2
- ANK2 | c.84+57117G>T | Intron (SNP) | VAF 87/308 reads (28%) | catalogued as COSV52180938; called by muse, mutect2, varscan2
- ANK2 | c.84+57118G>T | Intron (SNP) | VAF 88/304 reads (29%) | called by muse, mutect2, varscan2
- ANK3 | c.13065+1974G>T | Intron (SNP) | VAF 29/233 reads (12%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2156-3645G>T | Intron (SNP) | VAF 61/499 reads (12%) | called by muse, varscan2
- ARMC3 | c.2045+5215A>G | Intron (SNP) | VAF 61/291 reads (21%) | called by muse, mutect2, varscan2
- BABAM2 | c.1088+11606A>C | Intron (SNP) | VAF 27/270 reads (10%) | called by muse, mutect2, varscan2
- BBS4 | c.*176G>A | 3'UTR (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- BTN2A3P | n.1522C>G | RNA (SNP) | VAF 86/384 reads (22%) | called by muse, mutect2, varscan2
- C4orf50 | c.-943C>G | 5'UTR (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- CACNB2 | c.120+11C>G | Intron (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- CCDC57 | c.2242-5565C>G | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- CLPSL2 | c.*2G>A | 3'UTR (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- CNTFR | c.*6G>T | 3'UTR (SNP) | VAF 28/165 reads (17%) | called by muse, mutect2, varscan2
- DEUP1 | c.30-2953C>T | Intron (SNP) | VAF 27/169 reads (16%) | catalogued as rs1351370250; called by muse, mutect2, varscan2
- EFEMP2 | c.368-37G>A | Intron (SNP) | VAF 84/292 reads (29%) | catalogued as rs1213690279; called by muse, mutect2
- FBXO46 | c.*70G>A | 3'UTR (SNP) | VAF 6/94 reads (6%) | catalogued as rs1421008080; called by muse, mutect2
- IGKV2-29 | n.238G>T | RNA (SNP) | VAF 73/695 reads (11%) | catalogued as rs752008201; called by muse, mutect2
- IGKV2-29 | n.237G>A | RNA (SNP) | VAF 72/696 reads (10%) | catalogued as rs560145027; called by muse, mutect2
- KIF1A | c.*9C>T | 3'UTR (SNP) | VAF 13/101 reads (13%) | catalogued as rs751236889; called by muse, mutect2, varscan2
- KLHL14 | c.-43-471_-43-447del | Intron (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- LDHA | c.*263C>G | 3'UTR (SNP) | VAF 27/338 reads (8%) | catalogued as rs765088560; called by muse, mutect2
- LINC01551 | n.1254+18532C>A | Intron (SNP) | VAF 19/214 reads (9%) | called by muse, mutect2
- LINC01973 | n.1612C>A | RNA (SNP) | VAF 198/993 reads (20%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.370+16550G>C | Intron (SNP) | VAF 47/448 reads (10%) | called by muse, mutect2
- MED13L | c.5176-34G>C | Intron (SNP) | VAF 66/258 reads (26%) | called by muse, mutect2, varscan2
- NKAP | c.468-99C>A | Intron (SNP) | VAF 57/103 reads (55%) | called by muse, varscan2
- PTGER3 | c.1077+50C>A | Intron (SNP) | VAF 80/274 reads (29%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158839 A>T | 5'Flank (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- RNF114 | c.*37A>T | 3'UTR (SNP) | VAF 42/235 reads (18%) | called by muse, varscan2
- SNAP23 | c.*38G>T | 3'UTR (SNP) | VAF 19/153 reads (12%) | catalogued as COSV99987377; called by muse, mutect2, varscan2
- SPATA31C2 | n.2518A>T | RNA (SNP) | VAF 70/424 reads (17%) | called by muse, mutect2, varscan2
- STIM2 | c.1763+1483G>C | Intron (SNP) | VAF 38/544 reads (7%) | catalogued as COSV52840138; called by muse, mutect2
- UBE2DNL | n.628C>A | RNA (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- UBE2J2 | c.172+973C>A | Intron (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
